TARGET case TARGET-10-PARBGL — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08b174bc-1b1f-4985-b9d9-d3883e3d2ff8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.2 years (1,187 days); Year of diagnosis: 2007; Days to last follow up: 3,246 days (8.9 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 1,443 days (4.0 years); Days to first event: 1,443 days (4.0 years); First event: Relapse.
- Days to follow up: 3,246 days (8.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 66.9 ×10³/µL.
- Day 8: Bone Marrow blast count 52%; Minimal Residual Disease (Flow Cytometry) 0.17%.
- Day 15: Bone Marrow blast count 0%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.056%.

Biospecimens (3 samples)
- Samples TARGET-10-PARBGL-09A, TARGET-10-PARBGL-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARBGL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- First Event: Relapse (off-therapy)
- Overall Survival Time in Days: 3246
- WBC at Diagnosis: 66.9
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 0.17
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.056
- MRD Day 29 Sensitivity: 0.001
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 52
- BMA Blasts Day 15: 0
- BMA Blasts Day 29: 0
- Karyotype: 47,XX,+X,dup(7)(q11.2q22),del(9)(p21),dic(9;20)(p12;q11.2),del(11)(q22q25),del(11)(q23q25),+21[16]/46,XX[1]
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Transplant
- Cell of Origin: B-Precursor
